Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4897, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4897-01A (Primary Tumor).

Surgery Date: [REDACTED]

CGA - CJ - 4897

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY AND ADRENAL:
RENAL CELL CARCINOMA, CONVENTIONAL (90% CLEAR CELLS AND 10% EOSINOPHILIC CELLS),
FUHRMAN'S NUCLEAR GRADE 3.
TUMOR EXTENDS INTO THE PERINEPHRIC ADIPOSE TISSUE.
TUMOR INVADES THE ADRENAL GLAND. (SEE COMMENT)
TUMOR INVADES THE RENAL VEIN.
THE TUMOR MEASURES 13.5 CM IN MAXIMUM DIMENSION.
Vascular, ureteral and soft tissue margins, free of tumor.

COMMENT

The tumor extends into the perinephric adipose tissue compressing the adrenal gland. In addition, the tumor focally invades the adrenal gland by direct extension.

GROSS DESCRIPTION

(A) RIGHT KIDNEY AND ADRENAL - A nephrectomy specimen (25.5 x 16.5 x 9.0 cm) including compressed adrenal gland (6.0 x 3.0 x 0.1 cm) and ureter (8.0 x 0.5 cm).

A 13.5 x 9.0 x 0.5 cm solid and cystic, yellow-red, heterogeneous tumor is present. The tumor is mainly located within the upper lobe, extending to the mid third and lower pole of the kidney. The tumor has myxoid, degenerative-looking areas, as well as hemorrhagic and necrotic foci. The tumor involves the perinephric fat, bulging out from the kidney and extending up to the adrenal gland, which is grossly compressed by the tumor. The tumor involves the renal sinus but does not extend to the pelvicalyceal system. A tumoral thrombus is present intraluminally within the renal vein, 1.0 cm away from the vein margin. The soft tissue margins appear to be free of tumor. Portions of the tumor are submitted for possible electron microscopic studies and for tissue bank.

The uninvolved kidney parenchyma is unremarkable.

INK CODE: Black - soft tissue margin.

SECTION CODE: A1, renal vein, renal artery and ureter margins; A2-A7, tumor in relation to adrenal gland; A8-A12, tumor in relation to perinephric fat (A11 and A12 include tumor within the perinephric fat); A13, tumor within the renal sinus; A14, tumor in relation to the pelvicalyceal system; A15, A16, tumor within renal vein, in relation to pelvicalyceal system; A17, tumor with renal vein; A18, tumor within vein with adjacent renal parenchyma; A19, tumor with renal parenchyma; A20, nontumoral kidney parenchyma. [REDACTED]

CLINICAL HISTORY

Right renal mass.

SNOMED CODES

T-71000, T-B3000, M-83123

Source: NCI Genomic Data Commons file afb3ae2c-a00c-42ac-8e69-21f6f4dca97d (TCGA-CJ-4897.508E7910-02FC-4B42-8B89-B4DF86FAA878.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).